Somatic mutation profile of tumor specimen ALCH-AF4X-TTP1-A (aliquot ALCH-AF4X-TTP1-A-2-0-D-A667-36) from ALCHEMIST case ALCH-AF4X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.1 years (25,223 days).
Specimen ALCH-AF4X-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acf32443-2368-4449-9af0-40941c32036f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF4X-NB1-A (Blood Derived Normal), aliquot ALCH-AF4X-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce37105f-9330-4d7b-8a4a-359b645a173e

The open-access MAF lists 146 somatic variants for this specimen: 98 protein-altering or splice-affecting, 37 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 37, Intron 5, RNA 4, Splice Site 4, Frame Shift Del 3, Nonsense Mutation 3, 3'UTR 2, Splice Region 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 106/213 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853077, CM011960, CM981864; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP13A5 | c.2927C>T p.S976L | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as rs773354921, COSV100664638; called by muse, mutect2, varscan2
- CCDC168 | c.2225C>T p.T742M | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112022745; called by muse, mutect2, varscan2
- CDKL2 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 84/248 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV56735520; called by muse, mutect2, varscan2
- CEP290 | c.4865G>C p.R1622P | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CX1212121; called by muse, mutect2, varscan2
- COL11A1 | c.5207G>C p.G1736A | Missense Mutation (SNP) | VAF 161/294 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100616291, COSV62179850, COSV62188136; called by muse, mutect2, varscan2
- CR1L | c.1370C>A p.S457* | Nonsense Mutation (SNP) | VAF 115/429 reads (27%) | catalogued as COSV54331189; called by muse, mutect2, varscan2
- EGR4 | c.1645C>T p.R549C (on ENST00000545030; = p.R446C on NM_001965.4) | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1452996926, COSV101474257; called by muse, mutect2, varscan2
- EXOC3L4 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1483068497; called by muse, mutect2, varscan2
- EZHIP | c.769C>G p.R257G | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.229); catalogued as rs1275500691, COSV100539658, COSV100539891; called by muse, mutect2
- FCN2 | c.101-1G>C p.X34_splice | Splice Site (SNP) | VAF 56/236 reads (24%) | catalogued as COSV99052170; called by muse, mutect2, varscan2
- GTF3C1 | c.357G>C p.E119D | Missense Mutation (SNP) | VAF 164/562 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV99852170; called by muse, mutect2, varscan2
- H2BC21 | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 199/682 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58612160; called by muse, mutect2, varscan2
- HDGFL1 | c.444C>A p.S148R | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.023); catalogued as rs1175253849, COSV57751353, COSV57752503; called by muse, mutect2, varscan2
- IDH3B | c.916-8C>T | Splice Region (SNP) | VAF 20/205 reads (10%) | catalogued as rs1412842843; called by muse, mutect2
- ITGA8 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV65225918; called by muse, varscan2
- KEAP1 | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 107/241 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50263268; called by muse, mutect2
- KRT2 | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV59011858; called by muse, varscan2
- LAMA5 | c.7375G>T p.A2459S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53366114; called by muse, mutect2
- LRRFIP2 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763928513; called by muse, mutect2
- LY9 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 104/358 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.78); catalogued as rs752635349; called by muse, mutect2, varscan2
- MECR | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 119/334 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.323); catalogued as rs757058811; called by muse, mutect2, varscan2
- MEP1A | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 86/566 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs758951456, COSV57917846; called by muse, mutect2, varscan2
- MTMR6 | c.251G>C p.R84T | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV67808098; called by muse, mutect2
- MVK | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 92/435 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs104895355, CM068194; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- NUP205 | c.2983C>G p.L995V | Missense Mutation (SNP) | VAF 122/393 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV53656415; called by muse, mutect2, varscan2
- PHF8 | c.1936G>C p.E646Q (on ENST00000357988 / NM_001184896.1; = p.E610Q on NM_015107.3) | Missense Mutation (SNP) | VAF 121/182 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV57682260; called by muse, mutect2, varscan2
- PRH2 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.208); catalogued as rs776898585, COSV67171669; called by muse, mutect2
- PRKCB | c.1546C>G p.Q516E | Missense Mutation (SNP) | VAF 125/429 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.354); catalogued as COSV57774767; called by muse, mutect2, varscan2
- PTPRB | c.5965C>G p.H1989D | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV99717684; called by muse, mutect2
- RYR2 | c.12622G>T p.E4208* | Nonsense Mutation (SNP) | VAF 146/326 reads (45%) | catalogued as COSV63666630, COSV63692539; called by muse, mutect2, varscan2
- SCNN1D | c.1198C>A p.L400M (on ENST00000338555; = p.L564M on NM_001130413.4) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.796); catalogued as COSV57642256; called by muse, varscan2
- SETD5 | c.4123C>T p.P1375S | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.08); catalogued as rs756264715; called by muse, mutect2
- SOWAHB | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1339664927; called by muse, mutect2, varscan2
- UACA | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 65/284 reads (23%) | catalogued as rs1428584780, COSV59855368; called by muse, mutect2, varscan2
- VPS35L | c.2389C>G p.L797V | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV51977245; called by muse, varscan2
- ZNF236 | c.3775C>T p.R1259C | Missense Mutation (SNP) | VAF 150/488 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220031297, COSV53484522; called by muse, mutect2, varscan2
- ZNF98 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV63334101; called by muse, varscan2
- ADAMTS6 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 85/219 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- AKAP9 | c.3374C>T p.S1125L | Missense Mutation (SNP) | VAF 177/560 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH1L1 | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 100/347 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ARMC3 | c.2425del p.I809Lfs*7 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by mutect2, pindel, varscan2
- ARMH3 | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- C16orf78 | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- C20orf96 | c.1015C>G p.L339V (on ENST00000360321 / NM_153269.3; = p.L338V on NM_080571.1) | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC175 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 89/289 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP44 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 126/394 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CHD3 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CHL1 | c.508+2T>A p.X170_splice | Splice Site (SNP) | VAF 129/432 reads (30%) | called by muse, varscan2
- CPA4 | c.598T>C p.S200P | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- CPQ | c.480G>C p.Q160H | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSF2RA | c.1036T>A p.F346I | Missense Mutation (SNP) | VAF 19/524 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.051); called by muse, mutect2
- CSK | c.368_370del p.D123del | In Frame Del (DEL) | VAF 75/297 reads (25%) | called by mutect2, pindel, varscan2
- DCAF6 | c.647_672del p.V216Gfs*26 | Frame Shift Del (DEL) | VAF 122/465 reads (26%) | called by mutect2, pindel, varscan2
- DNAH3 | c.4199C>T p.P1400L | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DPH2 | c.1427G>A p.R476K | Missense Mutation (SNP) | VAF 97/297 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- DYNC2H1 | c.2056G>T p.A686S | Missense Mutation (SNP) | VAF 151/487 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EGLN3 | c.392G>C p.G131A | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ETFA | c.732A>C p.A244= | Splice Region (SNP) | VAF 138/512 reads (27%) | called by muse, mutect2, varscan2
- FBN3 | c.2324G>A p.C775Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FNDC1 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPLD1 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 133/246 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR88 | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.19); called by muse, varscan2
- GPRIN3 | c.1310A>G p.D437G | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRIN3A | c.2756C>A p.A919D | Missense Mutation (SNP) | VAF 129/403 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- HEPH | c.860A>G p.Q287R (on ENST00000343002; = p.Q20R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/111 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HERC6 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- HTRA4 | c.1130A>C p.N377T | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IARS2 | c.2135G>T p.G712V | Missense Mutation (SNP) | VAF 230/500 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- IGKV3D-20 | c.134C>A p.A45D | Missense Mutation (SNP) | VAF 161/244 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ILDR2 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 146/691 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KIAA1755 | c.2033dup p.T679Dfs*4 | Frame Shift Ins (INS) | VAF 28/125 reads (22%) | called by mutect2, pindel, varscan2
- KIAA2012 | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 130/416 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- LANCL3 | c.197A>T p.Y66F | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEL2 | c.2551G>T p.V851L | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MAP2K2 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.403); called by muse, mutect2
- MRPS15 | c.416A>C p.Y139S | Missense Mutation (SNP) | VAF 127/408 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- MYRFL | c.981-1G>C p.X327_splice | Splice Site (SNP) | VAF 30/512 reads (6%) | called by muse, mutect2
- NDRG3 | c.1082C>A p.S361Y (on ENST00000349004 / NM_032013.4; = p.S349Y on NM_022477.4) | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, varscan2
- NFXL1 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 48/360 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- NIPBL | c.89C>G p.S30C | Missense Mutation (SNP) | VAF 109/550 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NOL4 | c.1528C>A p.L510M | Missense Mutation (SNP) | VAF 92/271 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PCLO | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PDE4D | c.2239G>T p.D747Y (on ENST00000340635 / NM_001104631.2; = p.D611Y on NM_006203.4) | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP1R12B | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRODH2 | c.393C>A p.H131Q (on ENST00000301175; = p.H55Q on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- PROM1 | c.2446G>T p.A816S | Missense Mutation (SNP) | VAF 80/319 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PRPS1L1 | c.757T>A p.F253I | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- RIC8A | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 99/272 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SPPL2C | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- TIMP4 | c.664G>T p.V222F | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TM2D3 | c.686A>C p.D229A (on ENST00000333202 / NM_078474.3; = p.D203A on NM_025141.3) | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM125 | c.152del p.G51Afs*18 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by pindel, varscan2
- TSR3 | c.704-1G>A p.X235_splice | Splice Site (SNP) | VAF 27/295 reads (9%) | called by muse, mutect2
- TTLL3 | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TTN | c.91705G>C p.E30569Q (on ENST00000591111; = p.E23145Q on NM_003319.4) | Missense Mutation (SNP) | VAF 157/484 reads (32%) | PolyPhen benign (0.02); called by muse, mutect2, varscan2
- VCAN | c.3937C>A p.P1313T | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ZKSCAN2 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 93/337 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAM8 | c.12C>T p.L4= | Silent (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2, varscan2
- AKAP9 | c.10713C>T p.F3571= (on ENST00000359028; = p.F3547= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 92/336 reads (27%) | catalogued as COSV62358677; called by muse, mutect2, varscan2
- AL121899.2 | c.1842C>A p.P614= | Silent (SNP) | VAF 92/243 reads (38%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.1005G>T p.S335= | Silent (SNP) | VAF 45/173 reads (26%) | catalogued as COSV57322740; called by muse, mutect2, varscan2
- CYP11B1 | c.192G>T p.L64= | Silent (SNP) | VAF 161/536 reads (30%) | catalogued as COSV52829969; called by muse, mutect2, varscan2
- DENND2B | c.1152G>A p.V384= | Silent (SNP) | VAF 70/195 reads (36%) | called by muse, mutect2, varscan2
- DUSP5 | c.9C>G p.V3= | Silent (SNP) | VAF 44/126 reads (35%) | called by muse, mutect2, varscan2
- ETV1 | c.513A>G p.P171= | Silent (SNP) | VAF 122/346 reads (35%) | called by muse, mutect2, varscan2
- FAM135B | c.2580C>T p.H860= | Silent (SNP) | VAF 126/364 reads (35%) | called by muse, mutect2, varscan2
- FOXN3 | c.105A>T p.P35= | Silent (SNP) | VAF 166/535 reads (31%) | called by muse, mutect2, varscan2
- FSCN2 | c.342C>T p.T114= | Silent (SNP) | VAF 57/146 reads (39%) | catalogued as rs782415323; called by muse, mutect2, varscan2
- KCNA6 | c.183G>T p.L61= | Silent (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- KCNT1 | c.258C>T p.F86= (on ENST00000488444; = p.F105= on NM_020822.3) | Silent (SNP) | VAF 110/327 reads (34%) | called by muse, mutect2, varscan2
- KEAP1 | c.510C>G p.A170= | Silent (SNP) | VAF 110/252 reads (44%) | called by muse, mutect2
- LARGE2 | c.1695C>T p.F565= | Silent (SNP) | VAF 64/261 reads (25%) | called by muse, mutect2, varscan2
- LPA | c.3951C>T p.G1317= | Silent (SNP) | VAF 52/305 reads (17%) | called by muse, mutect2, varscan2
- LPA | c.3072C>T p.A1024= | Silent (SNP) | VAF 93/285 reads (33%) | called by muse, mutect2, varscan2
- MICA | c.984A>G p.L328= | Silent (SNP) | VAF 62/526 reads (12%) | called by muse, varscan2
- MPP7 | c.708C>G p.L236= | Silent (SNP) | VAF 64/183 reads (35%) | called by muse, mutect2, varscan2
- MYH7B | c.2319G>A p.L773= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV53420383; called by muse, mutect2, varscan2
- MYLK2 | c.1692C>G p.L564= | Silent (SNP) | VAF 194/605 reads (32%) | called by muse, mutect2, varscan2
- NLRX1 | c.1632G>A p.L544= | Silent (SNP) | VAF 43/107 reads (40%) | called by muse, varscan2
- NOL4L | c.204C>T p.P68= | Silent (SNP) | VAF 76/238 reads (32%) | called by muse, mutect2, varscan2
- NRXN1 | c.291C>T p.C97= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs973639826, COSV68017838; called by muse, mutect2, varscan2
- NUP155 | c.1407A>T p.V469= (on ENST00000231498 / NM_153485.3; = p.V410= on NM_004298.4) | Silent (SNP) | VAF 46/496 reads (9%) | called by muse, mutect2
- ONECUT2 | c.1053C>A p.I351= | Silent (SNP) | VAF 33/470 reads (7%) | catalogued as COSV101529825; called by muse, mutect2
- PCDH7 | c.999C>A p.A333= | Silent (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- PDGFD | c.432G>A p.T144= | Silent (SNP) | VAF 123/395 reads (31%) | catalogued as rs570808064, COSV56376965; called by muse, mutect2, varscan2
- PROM1 | c.2445G>T p.L815= | Silent (SNP) | VAF 84/328 reads (26%) | called by muse, mutect2, varscan2
- QRICH2 | c.813G>T p.V271= | Silent (SNP) | VAF 47/121 reads (39%) | called by muse, mutect2, varscan2
- RASGRP1 | c.927C>T p.L309= | Silent (SNP) | VAF 111/348 reads (32%) | called by muse, mutect2, varscan2
- REPS2 | c.144C>T p.A48= | Silent (SNP) | VAF 11/14 reads (79%) | called by muse, mutect2, varscan2
- SH2B3 | c.618C>T p.A206= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs1332931823; called by muse, mutect2, varscan2
- SLC4A1 | c.1620G>A p.L540= | Silent (SNP) | VAF 28/634 reads (4%) | catalogued as COSV52258304; called by muse, mutect2
- TBC1D8 | c.3297C>A p.V1099= | Silent (SNP) | VAF 66/628 reads (11%) | called by mutect2, varscan2
- UROC1 | c.1728C>T p.F576= | Silent (SNP) | VAF 196/611 reads (32%) | catalogued as rs373524871; called by muse, mutect2, varscan2
- YIPF3 | c.360C>T p.P120= | Silent (SNP) | VAF 18/346 reads (5%) | called by muse, mutect2
- AC073264.3 | n.214A>G | RNA (SNP) | VAF 128/585 reads (22%) | called by muse, varscan2
- AL035696.1 | n.307C>G | RNA (SNP) | VAF 44/665 reads (7%) | called by muse, mutect2
- EVI5L | c.1200+1030G>T | Intron (SNP) | VAF 153/336 reads (46%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102519G>T | Intron (SNP) | VAF 78/269 reads (29%) | catalogued as COSV59673568; called by muse, mutect2, varscan2
- HNRNPA3P1 | n.174G>T | RNA (SNP) | VAF 37/363 reads (10%) | called by muse, mutect2, varscan2
- IL7 | c.148-7011C>T | Intron (SNP) | VAF 15/398 reads (4%) | called by muse, mutect2
- KCNU1 | c.2010-16950G>T | Intron (SNP) | VAF 114/355 reads (32%) | called by muse, mutect2, varscan2
- LINC02817 | n.315T>A | RNA (SNP) | VAF 88/661 reads (13%) | called by muse, mutect2, varscan2
- NADK | c.393+30G>A | Intron (SNP) | VAF 22/122 reads (18%) | catalogued as rs781077320; called by muse, varscan2
- SHROOM4 | c.*1204A>G | 3'UTR (SNP) | VAF 5/70 reads (7%) | catalogued as rs1557245623, COSV104388442; called by muse, mutect2
- SMR3B | c.*207C>T | 3'UTR (SNP) | VAF 19/306 reads (6%) | called by muse, mutect2
